Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A8BO, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A8BO-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

....

Clinical Diagnosis & History:
Right leg mass.

Specimens Submitted:
1: Right leg mass sarcoma ???
2: Lateral fascial margin right leg

DIAGNOSIS:

1. Right leg mass sarcoma; excision:
- High grade spindle and pleomorphic sarcoma consistent with malignant fibrous histiocytoma/ undifferentiated high grade pleomorphic sarcoma.
- Tumor measures 9 x 6 x 4 cm.
- Tumor involves dermis, subcutis and extends to fascia.
- Necrosis is present about 15%.
- Tumor extends focally to the deep margin of resection and is located 0.1 cm from the lateral resection margin (Please see part 2). Tumor does not involve attached periosteum and portion of bone. All other margins are negative.

Note: Immunostains show that the tumor cells are negative for SMA, myogenin, desmin, S-100 and HMB45.

2. Lateral fascial margin right leg:
- Benign fibro-adipose tissue.

Some of the immunohistochemistry and ISH tests were developed and their performance characteristics were determined by the . They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA ' 88) as qualified to perform high complexity clinical laboratory testing.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

** Continued on next page **

ICD-O-3
Sarcoma, pleomorphic, undifferentiated
8802/3 8805/3
Code to highest 8805/3
Site R Leg NOS C49.2
JW 11/22/13

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

----- Page 2 of 3

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is labeled "right leg mass ?? sarcoma", long stitch lateral, short stitch superior. Received fresh is an ellipse of skin measuring 11 x 7 x 3.5 cm. The skin surface is tan to white to slightly hemorrhagic. Two stitches are identified, designated by the surgeon as above. The specimen is inked as follows: Black-deep, green-medial, blue-lateral, red-superior, yellow -inferior. Serial sectioning reveals a homogeneous tan/yellow, partially cystic and hemorrhagic mass measuring 9 x 6 x 4 cm. It appears to be within 1 mm from the deep and lateral margin. TPS is submitted and photos are taken. Representative sections are submitted as follows:

Summary of sections:

IM--inferior margin
TD- tumor to deep margin
TL-tumor to lateral margin
TM-tumor to medial margin
TS- tumor in relation to skin
TC- tumor in cystic and hemorrhagic areas
TF-tumor in relation to fat
T- tumor
NS- normal skin
SM- superior margin

2). The specimen is received in formalin labeled "Lateral fascial margin right leg." It consists of an elongated piece of brown-tan soft tissue measuring 4.0 x 0.5 x 0.5 cm. The specimen is sectioned and submitted entirely.

Summary of sections:

U - undesignated

Summary of Sections:

Part 1: Right leg mass sarcoma ???

Block	Sect.	Site	PCs
1		im	1
1		ns	1

** Continued on next page **

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

----- Page 3 of 3

1	sm	1
4	t	4
1	tc	1
2	td	2
1	tf	1
2	tl	2
2	tm	2
2	ts	2

Part 2: Lateral fascial margin right leg

Block	Sect.	Site	PCs
1		u	1

** End of Report **

Criteria	10/29/13	Yes	No

Source: NCI Genomic Data Commons file ed789983-35fa-4f6b-9998-82d3d4f7e4f6 (TCGA-DX-A8BO.CD89E7C9-AADE-4A80-876F-225A392B47FE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).